Somatic mutation profile of tumor specimen TCGA-A5-A0R6-01A (aliquot TCGA-A5-A0R6-01A-11D-A10B-09) from TCGA case TCGA-A5-A0R6, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Tumor grade: G3; Age at diagnosis: 64.2 years (23,449 days).
Specimen TCGA-A5-A0R6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f639d1e-e217-4bc8-93d0-1b8d3bc243c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A0R6-10A (Blood Derived Normal), aliquot TCGA-A5-A0R6-10A-01D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b45ece88-1e57-42eb-a178-41d7176d7fb9

The open-access MAF lists 55 somatic variants for this specimen: 43 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 34, Silent 12, Nonsense Mutation 3, Frame Shift Del 3, Splice Site 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1133G>A p.C378Y | Missense Mutation (SNP) | VAF 124/196 reads (63%) | hotspot (GDC flag); SIFT tolerated (0.86); PolyPhen benign (0.402); catalogued as rs397514565, CM126691, COSV55930877, COSV55952006; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3127A>G p.M1043V | Missense Mutation (SNP) | VAF 78/121 reads (64%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1057519936, COSV55879858, COSV55890961; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 22/48 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ALK | c.1846G>T p.G616* | Nonsense Mutation (SNP) | VAF 31/64 reads (48%) | catalogued as rs1451987798, COSV66589914; called by muse, mutect2, varscan2
- ANPEP | c.2667C>T p.N889= | Splice Region (SNP) | VAF 20/111 reads (18%) | catalogued as rs201439023, COSV55595351; called by muse, mutect2, varscan2
- BGN | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as rs782239175, COSV59038401, COSV59038579; called by muse, mutect2
- CAVIN4 | c.898A>G p.S300G | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs767144523, COSV56868422; called by muse, mutect2, varscan2
- CCDC102A | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs746272672, COSV50779614; called by muse, mutect2, varscan2
- CCDC114 | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs147082322, COSV100197158; called by muse, mutect2, varscan2
- CCN1 | c.1010G>A p.C337Y | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71704446; called by muse, mutect2
- CEP68 | c.23C>G p.A8G | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.811); catalogued as COSV53127588; called by muse, mutect2
- COL5A3 | c.931G>C p.V311L | Missense Mutation (SNP) | VAF 15/176 reads (9%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.956); catalogued as COSV53419405; called by muse, mutect2
- DKK2 | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV53403665; called by muse, mutect2, varscan2
- FAM50B | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs370896067; called by muse, mutect2, varscan2
- FHDC1 | c.2470C>T p.P824S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as rs749426190, COSV52603011; called by muse, mutect2, varscan2
- GNAO1 | c.1009G>C p.D337H | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52612047, COSV52620743; called by muse, mutect2
- HEATR4 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs528517201, COSV58569867; called by muse, mutect2, varscan2
- HEPH | c.1242T>A p.D414E (on ENST00000343002; = p.D147E on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57972458; called by muse, mutect2, varscan2
- HERC1 | c.14339C>T p.S4780F | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71250304; called by muse, mutect2, varscan2
- HOXC6 | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs763888269, COSV54537042; called by muse, mutect2, varscan2
- KDM6A | c.3022_3050del p.A1008Kfs*7 | Frame Shift Del (DEL) | VAF 42/190 reads (22%) | catalogued as COSV65046092; called by mutect2, pindel, varscan2
- KIF5B | c.244T>G p.F82V | Missense Mutation (SNP) | VAF 86/285 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56656339; called by muse, mutect2, varscan2
- LCE2C | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs748071194, COSV100909458, COSV64228548; called by muse, mutect2, varscan2
- MYBPC2 | c.3067A>T p.N1023Y | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV63099991; called by muse, mutect2, varscan2
- PARD3B | c.2779G>T p.A927S (on ENST00000406610 / NM_001302769.2; = p.A858S on NM_057177.7) | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV62531043; called by muse, mutect2, varscan2
- PCDHB1 | c.2318G>A p.R773H | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs201121650, COSV60629341; called by muse, mutect2, varscan2
- PI4KA | c.3640C>G p.L1214V | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.175); catalogued as COSV55423350; called by muse, mutect2
- PRMT7 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751951164, COSV59835763; called by muse, mutect2, varscan2
- SKOR1 | c.2440G>A p.D814N | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.303); catalogued as COSV58250158; called by muse, mutect2
- SLC19A1 | c.1456G>T p.V486L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs770683387, COSV60593820; called by muse, mutect2
- SLC4A8 | c.214C>G p.R72G | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as rs1159918133, COSV60656411, COSV60658344; called by muse, mutect2
- SMG6 | c.4153G>T p.E1385* | Nonsense Mutation (SNP) | VAF 3/41 reads (7%) | catalogued as COSV53976526; called by muse, mutect2
- SYNE1 | c.23192T>A p.L7731* (on ENST00000367255 / NM_182961.4; = p.L7660* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 53/116 reads (46%) | catalogued as COSV55105395; called by muse, mutect2, varscan2
- TAF3 | c.1381G>A p.D461N | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.838); catalogued as rs1057735, COSV60211763; called by muse, mutect2, varscan2
- THSD4 | c.1387A>G p.I463V | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV55984964; called by muse, mutect2, varscan2
- UFSP2 | c.145A>G p.N49D | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV52992970; called by muse, mutect2, varscan2
- UNC79 | c.7513G>A p.A2505T (on ENST00000393151 / NM_001346218.2; = p.A2328T on NM_020818.5) | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV56411443; called by muse, mutect2, varscan2
- ZNF404 | c.1265G>A p.R422H | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as rs759418336, COSV60989006; called by muse, mutect2, varscan2
- ZNF438 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV59200966; called by muse, mutect2, varscan2
- ABCA9 | c.3626del p.P1209Lfs*15 | Frame Shift Del (DEL) | VAF 57/120 reads (48%) | called by mutect2, pindel, varscan2
- ARID1A | c.3715+1_3715+40del p.X1239_splice | Splice Site (DEL) | VAF 26/126 reads (21%) | called by mutect2, pindel
- ASPHD2 | c.146del p.G49Afs*172 | Frame Shift Del (DEL) | VAF 4/41 reads (10%) | called by mutect2, pindel, varscan2
- LPAR6 | c.485_488dup p.N163Kfs*9 | Frame Shift Ins (INS) | VAF 14/46 reads (30%) | called by mutect2, pindel, varscan2
- C1orf94 | c.1587G>A p.L529= (on ENST00000488417 / NM_001134734.2; = p.L339= on NM_032884.5) | Silent (SNP) | VAF 50/168 reads (30%) | catalogued as COSV64915859; called by muse, mutect2, varscan2
- CIZ1 | c.2337G>A p.S779= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs756753256, COSV52974523; called by muse, mutect2, varscan2
- DCBLD2 | c.2238C>T p.D746= | Silent (SNP) | VAF 28/171 reads (16%) | catalogued as rs750744764, COSV54585453; called by muse, mutect2, varscan2
- EGFLAM | c.27C>A p.L9= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV59317811; called by muse, mutect2, varscan2
- ESF1 | c.957G>A p.T319= | Silent (SNP) | VAF 112/289 reads (39%) | catalogued as rs748657225, COSV52524440; called by muse, mutect2, varscan2
- FCER1A | c.700T>C p.L234= | Silent (SNP) | VAF 11/169 reads (7%) | catalogued as COSV63668499; called by muse, mutect2
- KCNH3 | c.1158C>T p.I386= | Silent (SNP) | VAF 24/37 reads (65%) | catalogued as rs368016044; called by muse, mutect2, varscan2
- MAGEB6B | c.468G>A p.S156= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs769173154; called by mutect2, varscan2
- POTEM | c.354C>A p.G118= | Silent (SNP) | VAF 38/716 reads (5%) | catalogued as COSV69153070; called by muse, mutect2
- RS1 | c.565C>T p.L189= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as rs375231198, COSV66105959, COSV66107481; called by muse, mutect2, varscan2
- VEGFA | c.258C>T p.C86= (on ENST00000523873 / NM_001171623.1; = p.C266= on NM_003376.6) | Silent (SNP) | VAF 5/93 reads (5%) | catalogued as COSV57879931; called by muse, mutect2
- ZNF536 | c.3738G>A p.A1246= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs763122092, COSV62817654; called by muse, mutect2
